Somatic mutation profile of tumor specimen C3N-01524-02 (aliquot CPT0077300009) from CPTAC case C3N-01524, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 61.8 years (22,558 days).
Specimen C3N-01524-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c029558-f11a-4223-9cbb-4da56208ee28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01524-71 (Blood Derived Normal), aliquot CPT0077410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/157ec3a8-e5de-45fd-844d-9dbd3cc56eda

The open-access MAF lists 122 somatic variants for this specimen: 91 protein-altering or splice-affecting, 19 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 19, Nonsense Mutation 7, 3'UTR 6, Frame Shift Del 5, Intron 4, Frame Shift Ins 3, Splice Region 2, RNA 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 122/233 reads (52%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs869025631, CD141834, CM951280, HM971583, COSV56542714, COSV56543921; ClinVar: pathogenic; called by muse, mutect2, varscan2
- C1orf87 | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64596508; called by muse, mutect2
- CEMP1 | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV99566116; called by muse, mutect2
- CEP41 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 117/334 reads (35%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs782784827, COSV56219159; called by muse, mutect2, varscan2
- CHRNA2 | c.860T>C p.F287S | Missense Mutation (SNP) | VAF 140/370 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1060503073; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLSTN3 | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs148818256, COSV99867181; called by muse, mutect2, varscan2
- CNTN3 | c.2237C>A p.T746N | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.296); catalogued as COSV55185594; called by muse, mutect2, varscan2
- CP | c.2536G>C p.V846L | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.324); catalogued as rs1321940071; called by muse, mutect2, varscan2
- DPYSL4 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.954); catalogued as COSV58308937; called by muse, mutect2, varscan2
- HPS3 | c.980C>A p.T327K | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV56054075; called by muse, mutect2, varscan2
- IGLV4-3 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 44/285 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.387); catalogued as rs754142164; called by muse, mutect2, varscan2
- KIF13A | c.4235A>G p.Q1412R | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs771426174; called by muse, mutect2, varscan2
- KRTAP9-4 | c.143G>T p.C48F | Missense Mutation (SNP) | VAF 176/503 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs1336276656, COSV100484848; called by muse, mutect2, varscan2
- MUC17 | c.6628A>C p.M2210L | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs1016884814; called by muse, mutect2, varscan2
- MYL7 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56267371; called by muse, mutect2, varscan2
- PACS2 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs1209362754; called by muse, mutect2, varscan2
- PPFIA2 | c.1700C>A p.S567Y | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.323); catalogued as COSV61035926; called by muse, mutect2, varscan2
- PRMT8 | c.974C>A p.S325Y | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV54212189; called by muse, mutect2, varscan2
- PRPF8 | c.5624A>G p.H1875R | Missense Mutation (SNP) | VAF 63/350 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV59261977, COSV59266339; called by muse, mutect2, varscan2
- RHOB | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99695119; called by muse, mutect2
- RTTN | c.4105G>A p.A1369T | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV99731035; called by muse, varscan2
- UBE2L3 | c.43C>G p.R15G | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV100641576; called by muse, mutect2, varscan2
- WWC1 | c.942G>A p.R314= | Splice Region (SNP) | VAF 78/160 reads (49%) | catalogued as COSV54649621; called by muse, mutect2, varscan2
- ZNF527 | c.482G>C p.R161T | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.048); catalogued as COSV62236139; called by muse, mutect2, varscan2
- ACY3 | c.217T>G p.F73V | Missense Mutation (SNP) | VAF 79/219 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- AKAP12 | c.2608G>T p.E870* | Nonsense Mutation (SNP) | VAF 38/208 reads (18%) | called by muse, mutect2, varscan2
- AOPEP | c.2083A>T p.K695* (on ENST00000375315 / NM_001193329.1; = p.K596* on NM_032823.5) | Nonsense Mutation (SNP) | VAF 85/219 reads (39%) | called by muse, mutect2, varscan2
- ATP5IF1 | c.296T>G p.I99S | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4120A>C p.T1374P | Missense Mutation (SNP) | VAF 111/307 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CAMTA1 | c.3131A>C p.K1044T | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- CCDC9 | c.1411T>A p.F471I | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDK13 | c.2861A>C p.K954T | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CIPC | c.976A>T p.K326* | Nonsense Mutation (SNP) | VAF 89/208 reads (43%) | called by muse, mutect2, varscan2
- CIRBP | c.213dup p.V72Cfs*45 | Frame Shift Ins (INS) | VAF 49/208 reads (24%) | called by mutect2, pindel, varscan2
- CNDP2 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- CNDP2 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- CPLX4 | c.313dup p.D105Gfs*8 | Frame Shift Ins (INS) | VAF 48/148 reads (32%) | called by mutect2, pindel, varscan2
- CTNNA1 | c.1628G>T p.G543V | Missense Mutation (SNP) | VAF 138/614 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUBN | c.343T>A p.S115T | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CYFIP2 | c.2794_2795del p.F932Rfs*58 (on ENST00000616178 / NM_001291722.2; = p.F907Rfs*58 on NM_014376.4) | Frame Shift Del (DEL) | VAF 55/270 reads (20%) | called by mutect2, pindel, varscan2
- DDX46 | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by muse, varscan2
- DEPDC1 | c.165C>A p.D55E | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAJC11 | c.940T>G p.F314V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- DSCAM | c.1237T>C p.F413L | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- EPHB2 | c.2104A>C p.M702L (on ENST00000400191 / NM_001309193.2; = p.M703L on NM_004442.7) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EXOSC2 | c.773A>T p.Y258F | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FAM120B | c.1638G>T p.M546I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- FSIP2 | c.14243T>C p.I4748T | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- GPHN | c.1664T>A p.L555H (on ENST00000315266 / NM_001377519.1; = p.L588H on NM_020806.5) | Missense Mutation (SNP) | VAF 91/236 reads (39%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- IRAG1 | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNF1 | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- KCNH3 | c.1690del p.E564Sfs*76 | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | called by mutect2, pindel*
- KCNH5 | c.629A>C p.Y210S | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCTD9 | c.593_599del p.S198Yfs*11 | Frame Shift Del (DEL) | VAF 50/229 reads (22%) | called by mutect2, pindel, varscan2
- KIAA1217 | c.3182dup p.L1062Tfs*21 | Frame Shift Ins (INS) | VAF 5/53 reads (9%) | called by mutect2, pindel, varscan2
- KIF20B | c.1937T>A p.V646D | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- KIF5C | c.1044del p.E349Rfs*8 | Frame Shift Del (DEL) | VAF 15/67 reads (22%) | called by mutect2, pindel, varscan2
- KRTAP5-11 | c.336C>A p.C112* | Nonsense Mutation (SNP) | VAF 210/627 reads (33%) | called by muse, mutect2, varscan2
- LLGL1 | c.3049A>T p.T1017S | Missense Mutation (SNP) | VAF 89/256 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP1A | c.3745C>T p.H1249Y | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MEGF11 | c.1936T>A p.S646T | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- MTHFSD | c.349C>G p.Q117E (on ENST00000360900 / NM_001159377.2; = p.Q116E on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCAPG | c.2852G>T p.R951I | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- OVCH1 | c.3322A>T p.S1108C | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2
- P4HA2 | c.288C>G p.D96E | Missense Mutation (SNP) | VAF 62/260 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PHF20 | c.1092del p.E364Dfs*7 | Frame Shift Del (DEL) | VAF 44/170 reads (26%) | called by mutect2, pindel, varscan2
- PIKFYVE | c.1145C>A p.P382H | Missense Mutation (SNP) | VAF 78/207 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRRC2B | c.2255T>C p.L752P | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- PSEN1 | c.722T>C p.L241P | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEPTIN9 | c.826T>C p.F276L (on ENST00000427177 / NM_001113491.2; = p.F258L on NM_006640.4) | Missense Mutation (SNP) | VAF 123/323 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SI | c.2210G>C p.G737A | Missense Mutation (SNP) | VAF 94/272 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SLC35F1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SLC37A3 | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SMTNL1 | c.1098C>G p.F366L (on ENST00000399154; = p.F403L on NM_001105565.2) | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOX2 | c.103A>T p.K35* | Nonsense Mutation (SNP) | VAF 56/292 reads (19%) | called by muse, mutect2, varscan2
- SPRED3 | c.1129G>T p.V377L | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- STAG1 | c.300C>A p.S100= | Splice Region (SNP) | VAF 68/182 reads (37%) | called by muse, mutect2, varscan2
- TACC2 | c.7954C>A p.P2652T (on ENST00000334433; = p.P730T on NM_006997.4) | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- TACR3 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TAOK2 | c.1241C>G p.S414C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TFEC | c.173C>A p.S58* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- THSD7B | c.1293T>A p.C431* | Nonsense Mutation (SNP) | VAF 31/85 reads (36%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.4796G>A p.G1599D | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TUBGCP3 | c.2496G>C p.R832S | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- UBE2A | c.122T>G p.F41C | Missense Mutation (SNP) | VAF 91/123 reads (74%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP21 | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- USP29 | c.2245C>G p.Q749E | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WDR47 | c.1202A>G p.E401G (on ENST00000369962 / NM_001142551.2; = p.E402G on NM_014969.5) | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZMYM4 | c.2642A>C p.D881A | Missense Mutation (SNP) | VAF 76/240 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ZPBP | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 82/208 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ZSWIM5 | c.3200G>T p.S1067I | Missense Mutation (SNP) | VAF 44/238 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ABCC11 | c.855C>T p.C285= | Silent (SNP) | VAF 20/226 reads (9%) | catalogued as rs138005798, COSV100750500; called by muse, mutect2
- ATP2B2 | c.1701G>T p.L567= (on ENST00000352432; = p.L533= on NM_001683.5) | Silent (SNP) | VAF 45/73 reads (62%) | called by muse, mutect2, varscan2
- CCIN | c.1125G>A p.G375= | Silent (SNP) | VAF 43/176 reads (24%) | catalogued as rs17851732, COSV100631678, COSV58725995; called by muse, mutect2, varscan2
- CUBN | c.1440A>C p.G480= | Silent (SNP) | VAF 100/265 reads (38%) | called by muse, mutect2, varscan2
- DGAT2 | c.1023C>A p.P341= | Silent (SNP) | VAF 31/134 reads (23%) | called by muse, varscan2
- DLGAP2 | c.1023G>A p.K341= | Silent (SNP) | VAF 64/162 reads (40%) | catalogued as rs371562156; called by muse, mutect2, varscan2
- FRMPD4 | c.3138A>T p.G1046= | Silent (SNP) | VAF 95/128 reads (74%) | called by muse, mutect2, varscan2
- GAB4 | c.1503C>T p.S501= | Silent (SNP) | VAF 45/262 reads (17%) | catalogued as rs755347977, COSV68754459; called by muse, mutect2, varscan2
- GLI2 | c.3942C>T p.S1314= (on ENST00000361492 / NM_001374353.1; = p.S1331= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2, varscan2
- GPHN | c.1665C>A p.L555= (on ENST00000315266 / NM_001377519.1; = p.L588= on NM_020806.5) | Silent (SNP) | VAF 90/232 reads (39%) | called by muse, mutect2, varscan2
- JUNB | c.381C>T p.G127= | Silent (SNP) | VAF 53/122 reads (43%) | catalogued as rs776344055; called by muse, mutect2, varscan2
- KLHDC7A | c.1956G>A p.A652= | Silent (SNP) | VAF 102/281 reads (36%) | catalogued as rs1035779858; called by muse, mutect2, varscan2
- MARVELD1 | c.189C>T p.F63= | Silent (SNP) | VAF 130/340 reads (38%) | catalogued as rs1171788759; called by muse, mutect2, varscan2
- NEURL2 | c.834T>C p.L278= | Silent (SNP) | VAF 49/145 reads (34%) | called by muse, mutect2, varscan2
- RYR2 | c.8019G>A p.A2673= | Silent (SNP) | VAF 37/219 reads (17%) | catalogued as rs745484020, COSV63711534; called by muse, mutect2, varscan2
- TADA2A | c.1299C>T p.F433= | Silent (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- TBC1D9 | c.60C>A p.A20= | Silent (SNP) | VAF 72/233 reads (31%) | called by muse, mutect2, varscan2
- TRIM3 | c.921A>C p.R307= | Silent (SNP) | VAF 45/297 reads (15%) | called by muse, mutect2, varscan2
- UTP20 | c.1896C>T p.P632= | Silent (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- ANKLE2 | c.1700+37C>G | Intron (SNP) | VAF 88/225 reads (39%) | called by muse, mutect2, varscan2
- BRSK2 | c.91+21024C>A | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100373144; called by muse, mutect2
- CASZ1 | c.506-85_506-78delinsA | Intron (DEL) | VAF 13/50 reads (26%) | called by pindel, varscan2*
- CHRNA4 | c.*3184G>T | 3'UTR (SNP) | VAF 44/258 reads (17%) | called by muse, varscan2
- CHRNA4 | c.*3177C>T | 3'UTR (SNP) | VAF 52/246 reads (21%) | called by muse, varscan2
- GYS1 | c.*918A>G | 3'UTR (SNP) | VAF 134/402 reads (33%) | catalogued as rs1484203468; called by muse, mutect2, varscan2
- NAT8L | c.*51C>T | 3'UTR (SNP) | VAF 17/27 reads (63%) | catalogued as rs1465923459; called by muse, mutect2, varscan2
- PDIA3P1 | n.1265G>T | RNA (SNP) | VAF 86/228 reads (38%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159236 G>A | 5'Flank (SNP) | VAF 18/87 reads (21%) | catalogued as rs761417825; called by muse, mutect2, varscan2
- TUBB8P7 | n.894+216C>G | Intron (SNP) | VAF 100/308 reads (32%) | catalogued as rs556213255; called by muse, mutect2, varscan2
- UMPS | c.*1306G>A | 3'UTR (SNP) | VAF 32/111 reads (29%) | called by muse, mutect2, varscan2
- VAPB | c.*6170A>G | 3'UTR (SNP) | VAF 50/322 reads (16%) | catalogued as rs1172185375; called by muse, mutect2, varscan2
